Gene-level copy-number profile of tumor specimen TCGA-EO-A3KW-01A from TCGA case TCGA-EO-A3KW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 72.5 years (26,492 days).
Specimen TCGA-EO-A3KW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.9f2fa014-c04b-45c8-ac72-8720574ca7fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A3KW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e8249d2c-4756-467f-a93c-667400f66e32

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 15; copy number 2: 5,256; copy number 3: 16,087; copy number 4: 29,555; copy number 5: 5,742; copy number 6: 1,539; copy number 7: 789; copy number 8: 447; copy number 9: 115; copy number 10: 46; copy number 11: 116; copy number 12: 4; copy number 13: 8; copy number 14: 85; copy number 31: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A3KW-01A-11D-A227-01): tumor purity 0.72, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 380 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,193,901–202,319,781, 1 gene, copy number 9 (within-gene range 4–9): LGR6.
- chr2:3,658,200–3,704,153, 3 genes, copy number 12: ALLC, GAPDHP48, AC010907.1.
- chr2:5,313,740–5,556,031, 2 genes, copy number 14: AC073143.1, AC107057.1.
- chr2:11,658,178–11,676,925, 3 genes, copy number 11: NTSR2, CDK8P1, AC106875.2.
- chr2:11,681,460–11,683,328, 1 gene, copy number 11: AC106875.1.
- chr2:15,668,684–15,744,339, 2 genes, copy number 11–12 (within-gene range 4–14): AC008278.1, LINC01804.
- chr2:17,284,292–17,284,895, 1 gene, copy number 11: ZFYVE9P2.
- chr2:32,165,046–32,323,002, 7 genes, copy number 13: AL121658.1, SLC30A6, DDX50P1, RNU6-647P, NLRC4, YIPF4, AL133245.1.
- chr2:32,377,631–32,379,599, 1 gene, copy number 13: BIRC6-AS1.
- chr3:45,082,277–45,255,620, 4 genes, copy number 9: CDCP1, RPS24P8, TMEM158, U3.
- chr3:49,940,007–50,328,251, 22 genes, copy number 10 (within-gene range 4–10): RBM6, RBM5, RBM5-AS1, SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2, HYAL3, NAA80, HYAL1, HYAL2, TUSC2.
- chr3:160,753,428–173,336,965, 154 genes, copy number 11–31 (within-gene range 8–31) (broad region; genes not listed).
- chr3:197,445,061–198,222,513, 32 genes, copy number 9: AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:1,550,284–1,982,207, 12 genes, copy number 10: AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22.
- chr4:1,986,384–1,986,477, 1 gene, copy number 10: MIR943.
- chr17:26,981,694–28,445,563, 75 genes, copy number 9 (broad region; genes not listed).
- chr17:28,467,822–28,538,900, 3 genes, copy number 9 (within-gene range 7–9): RPS7P1, SLC13A2, FOXN1.
- chr17:49,966,075–50,130,160, 11 genes, copy number 10: RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14.
- chr19:28,294,093–29,921,653, 40 genes, copy number 11: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58.
- chr22:26,521,996–26,596,717, 1 gene, copy number 11 (within-gene range 6–11): TPST2.
- chr22:26,560,526–26,630,669, 4 genes, copy number 11: HMGB1P10, Z95115.2, CRYBB1, CRYBA4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
